Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4844, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4844-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN GRADE 3 OF 4, 8.2 cm IN GREATEST DIMENSION.
- B. APPROXIMATELY 10% OF THE EXAMINED TUMOR VOLUME SHOWS NECROSIS.
- C. EXTENSIVE INVASION OF THE PERINEPHRIC ADIPOSE TISSUE BY RENAL CELL CARCINOMA IS IDENTIFIED.
- D. RENAL CELL CARCINOMA IS PRESENT AT THE DEEP SURGICAL (GEROTA'S/FACIA) MARGIN.
- E. EXTENSIVE ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. VASCULAR AND URETERAL RESECTION MARGINS, AND RENAL SINUS/HILAR ADIPOSE TISSUE, ARE NEGATIVE FOR NEOPLASIA.
- G. THE ADRENAL GLAND SHOWS NO SIGNIFICANT PATHOLOGIC ABNORMALITY.
- H. NON-NEOPLASTIC RENAL PARENCHYMA SHOWS NO SIGNIFICANT PATHOLOGIC ABNORMALITY.
- I. PATHOLOGIC TNM STAGING: pT3a+ Nx Mx (see comment).

Source: NCI Genomic Data Commons file 819aac08-4b8c-47c2-b19b-9fca216653ac (TCGA-B0-4844.8F319BD4-D2A1-4221-9FC6-50AF12DD81D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).